Somatic mutation profile of tumor specimen TARGET-10-PAPIGV-09A (aliquot TARGET-10-PAPIGV-09A-01D) from TARGET case TARGET-10-PAPIGV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,387 days).
Specimen TARGET-10-PAPIGV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a75f31cf-1472-47a6-acf6-ec749cd0dda8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPIGV-14A (Bone Marrow Normal), aliquot TARGET-10-PAPIGV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0340dd4d-0b30-4847-99ea-cc27bb8c649b

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EXD2 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs766419235; called by muse, mutect2, varscan2
- KLHL22 | c.1669G>A p.G557S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.363); catalogued as rs763908252; called by muse, mutect2, varscan2
- NCKAP5 | c.2968G>C p.E990Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV100489952; called by muse, mutect2
- RBMXL3 | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV57747948; called by muse, mutect2
- RYR2 | c.5580G>C p.E1860D | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1263897515; called by muse, mutect2, varscan2
- ZNF222 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 39/97 reads (40%) | catalogued as rs772833717, COSV51828087; called by muse, mutect2, varscan2
- C2orf16 | c.3459dup p.R1154Tfs*4 | Frame Shift Ins (INS) | VAF 33/88 reads (38%) | called by mutect2, pindel, varscan2
- DMBT1 | c.6722C>A p.A2241D (on ENST00000338354 / NM_001377530.1; = p.A1484D on NM_004406.3) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- DNAJC28 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 12/209 reads (6%) | called by muse, mutect2
- EXOC1 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.103); called by muse, mutect2
- TPTE | c.706G>A p.D236N (on ENST00000618007 / NM_199261.4; = p.D218N on NM_199259.4) | Missense Mutation (SNP) | VAF 49/658 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- USH2A | c.8761T>G p.L2921V | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- ZNF595 | c.1912C>T p.H638Y | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2
- DNAH9 | c.4638C>A p.I1546= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as COSV52352728; called by muse, mutect2, varscan2
- GALNT2 | c.1641C>T p.S547= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs760210700, COSV64196007; called by muse, mutect2, varscan2
- KIAA1755 | c.2562C>T p.S854= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs143020541; called by mutect2, varscan2
- LRRC8B | c.933C>A p.I311= | Silent (SNP) | VAF 17/208 reads (8%) | catalogued as rs1226145104, COSV58373161; called by muse, mutect2
- PRICKLE1 | c.2061G>A p.L687= | Silent (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
